TCGA case TCGA-PL-A8LX — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Institute of Human Virology Nigeria. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fe2cd610-aa52-4789-ac62-7683281bb22f

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: Nigeria; Age at index: 35 years; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 35.2 years (12,840 days); Year of diagnosis: 2013; Method of diagnosis: Excisional Biopsy; AJCC staging edition: 7th; AJCC pathologic T: T4; AJCC pathologic N: N1a; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Bone, NOS / Liver / Breast, NOS / Breast, Left Upper Outer.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 5 days; Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-PL-A8LX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Days to sample procurement: 0 days; Initial weight: 540 mg.
  Slide TCGA-PL-A8LX-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-PL-A8LX-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: With tumor; Lymph nodes examined: Yes; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); Prospective collection: Yes; Retrospective collection: No.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Left; Anatomic organ subdivision: Left Upper Outer Quadrant.
- First nonlymph node metastasis anatomic sites: Metastasis site: Bone; Metastasis site: Liver.
- Follow-up form: Lost to follow-up: Yes; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 5 days; disease-specific survival: no event (censored), 5 days; progression-free interval: no event (censored), 5 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-PL-A8LX-01A-11D-A41E-01): tumor purity 0.57, ploidy 3.58, whole-genome doublings 1.
